Somatic mutation profile of tumor specimen TCGA-NH-A6GC-01A (aliquot TCGA-NH-A6GC-01A-12D-A40P-10) from TCGA case TCGA-NH-A6GC, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IVB; Age at diagnosis: 66.7 years (24,355 days).
Specimen TCGA-NH-A6GC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b47d69b5-d1b8-45b6-b42f-035fd3900334.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A6GC-10A (Blood Derived Normal), aliquot TCGA-NH-A6GC-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/692c8eb5-2b15-4155-bf3c-875b62cf8480

The open-access MAF lists 123 somatic variants for this specimen: 99 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 22, Nonsense Mutation 8, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, Splice Site 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 71/133 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.2352T>G p.Y784* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as rs886044330, COSV101370957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 41/53 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754861621, COSV50746909; called by muse, mutect2, varscan2
- ADGRB1 | c.3365G>T p.G1122V | Missense Mutation (SNP) | VAF 178/337 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60103807; called by muse, varscan2
- AEBP1 | c.218del p.G73Afs*219 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs112298043; called by mutect2, pindel, varscan2
- AKAP12 | c.4303G>T p.A1435S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99484708; called by muse, mutect2, varscan2
- ANKRD9 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.284); catalogued as rs750170448, COSV99743507; called by mutect2, varscan2
- APC | c.4455del p.D1486Ifs*21 | Frame Shift Del (DEL) | VAF 100/121 reads (83%) | catalogued as COSV57321956; called by mutect2, varscan2
- ARHGAP32 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs770485511, COSV100089789; called by muse, mutect2, varscan2
- ARL11 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as rs994780789, COSV56290713; called by muse, mutect2, varscan2
- ATF7 | c.1090C>T p.R364* (on ENST00000548446 / NM_001366555.2; = p.R353* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/32 reads (66%) | catalogued as COSV60643520; called by muse, mutect2, varscan2
- ATP10B | c.2345C>G p.T782S | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs960020951, COSV100515985; called by muse, mutect2, varscan2
- CADM4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99731745; called by muse, mutect2, varscan2
- CDH10 | c.1710C>A p.D570E | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053585; called by muse, mutect2, varscan2
- CIDEA | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.862); catalogued as rs751972278, COSV57598855; called by muse, mutect2, varscan2
- CLEC4D | c.371C>G p.T124R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100223231; called by muse, mutect2, varscan2
- COL6A3 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.623); catalogued as COSV99802432; called by muse, mutect2, varscan2
- CRTAP | c.1188A>T p.E396D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV58015161; called by muse, mutect2, varscan2
- DCAF4L2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs367683322; called by muse, mutect2, varscan2
- DENND2C | c.2654A>G p.K885R (on ENST00000393274 / NM_001256404.2; = p.K828R on NM_198459.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV101283992; called by muse, mutect2, varscan2
- DNAH9 | c.12704A>G p.E4235G | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV99308937; called by muse, mutect2, varscan2
- EIF2AK3 | c.1216A>T p.K406* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100304259; called by muse, mutect2, varscan2
- ELAPOR1 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV100884499; called by muse, mutect2, varscan2
- EMC1 | c.1434T>G p.D478E | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV100916478; called by muse, mutect2, varscan2
- EN1 | c.355_356insC p.K119Tfs*27 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | catalogued as COSV54632685; called by mutect2, pindel, varscan2
- EP400 | c.5857G>A p.V1953M | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100202605; called by muse, mutect2, varscan2
- FAM120B | c.1841C>G p.A614G | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.897); catalogued as COSV99380181; called by muse, mutect2, varscan2
- FAT4 | c.12079T>A p.F4027I | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100630663; called by muse, mutect2, varscan2
- FRAS1 | c.7454C>T p.T2485M | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs771971412, COSV53589559, COSV53629669; called by muse, mutect2, varscan2
- GPR150 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV101187440; called by muse, mutect2
- GTF3C2 | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); catalogued as COSV99273430; called by muse, mutect2, varscan2
- H1-2 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642342; called by muse, mutect2, varscan2
- H2AC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs374698925; called by muse, mutect2, varscan2
- H2BC3 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.114); catalogued as COSV100778326; called by muse, mutect2, varscan2
- HS3ST2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV99758554; called by muse, mutect2
- HSD17B2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752344353, COSV52274074; called by muse, mutect2
- HYAL2 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1553716156, COSV100753990; called by muse, mutect2, varscan2
- JAK3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as rs201784993, COSV71686009; called by muse, mutect2, varscan2
- KDM4A | c.1743T>G p.D581E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100969722; called by muse, mutect2, varscan2
- LCE2D | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV64228990; called by muse, mutect2, varscan2
- LMBRD1 | c.578C>G p.S193C (on ENST00000649011; = p.S171C on NM_018368.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV65297166; called by muse, mutect2, varscan2
- MAP9 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV100251192; called by muse, mutect2, varscan2
- MED27 | c.802-1G>C p.X268_splice | Splice Site (SNP) | VAF 30/174 reads (17%) | catalogued as COSV99406974; called by muse, mutect2, varscan2
- MGAM | c.4708C>T p.R1570C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601326, COSV72074844; called by muse, mutect2, varscan2
- MLLT3 | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 100/315 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV100581842; called by muse, mutect2, varscan2
- MPDZ | c.6175C>T p.R2059W (on ENST00000319217 / NM_001330637.2; = p.R2030W on NM_003829.5) | Missense Mutation (SNP) | VAF 106/184 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745768687, COSV59919342; called by muse, mutect2, varscan2
- MYO15A | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs1449403411, COSV99231658, COSV99234967; called by muse, mutect2, varscan2
- MYOM1 | c.3076A>C p.S1026R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99868914; called by muse, mutect2, varscan2
- NAA25 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs150077724; called by muse, mutect2, varscan2
- NAPB | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV100582713; called by muse, mutect2, varscan2
- NEB | c.3396G>T p.K1132N | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV51463667; called by muse, mutect2, varscan2
- NPY2R | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV100279994; called by muse, mutect2, varscan2
- NRXN2 | c.2769G>T p.K923N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV99636458; called by muse, mutect2, varscan2
- NSD3 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100389041; called by muse, mutect2, varscan2
- OBSL1 | c.3103C>A p.L1035M | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54710844; called by muse, mutect2, varscan2
- OR10K2 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59222942; called by muse, mutect2, varscan2
- OR14A16 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100713896, COSV62927292; called by muse, mutect2, varscan2
- OR1M1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1332959232, COSV101447568, COSV101447600; called by muse, mutect2, varscan2
- OR51A4 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100985403, COSV66749538; called by muse, varscan2
- PAK3 | c.385A>T p.K129* (on ENST00000262836 / NM_001324328.2; = p.K114* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/397 reads (4%) | catalogued as COSV53278106; called by muse, mutect2
- PAQR9 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.422); catalogued as rs1385030857, COSV100503984; called by muse, mutect2, varscan2
- PBX2 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100904083; called by muse, mutect2, varscan2
- PCDHA2 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65366037; called by muse, mutect2, varscan2
- PCDHA8 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 116/137 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100971126; called by muse, mutect2, varscan2
- PECR | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370330623; called by muse, mutect2, varscan2
- PNMA2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101580573, COSV72908619; called by muse, mutect2, varscan2
- PTPRU | c.3310A>T p.M1104L | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60537383; called by muse, mutect2, varscan2
- PTPRZ1 | c.4688A>C p.E1563A | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV66446335; called by muse, mutect2, varscan2
- RASAL2 | c.277A>C p.K93Q | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV100863007; called by muse, mutect2, varscan2
- RGP1 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100960424; called by muse, mutect2, varscan2
- ROBO2 | c.2500G>C p.G834R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV59942276; called by muse, mutect2, varscan2
- RP1L1 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1260752489, COSV101223795; called by muse, mutect2, varscan2
- SFSWAP | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV99906512; called by muse, mutect2, varscan2
- SGTA | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs780242378, COSV55594153; called by muse, mutect2, varscan2
- SHANK1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs376765376; called by muse, mutect2, varscan2
- SLC12A9 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759189306, COSV51931865; called by muse, mutect2, varscan2
- SLC26A9 | c.2083G>A p.V695M | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs766227284, COSV61605810; called by muse, mutect2, varscan2
- SLC30A7 | c.1072_1073insG p.I358Sfs*15 | Frame Shift Ins (INS) | VAF 32/158 reads (20%) | catalogued as COSV63018766; called by mutect2, pindel, varscan2
- SLCO2B1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs543049597, COSV56935587; called by muse, mutect2, varscan2
- SLX4 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs758029323, COSV53560580; called by muse, mutect2, varscan2
- SYNE1 | c.6103C>A p.L2035I (on ENST00000367255 / NM_182961.4; = p.L2042I on NM_033071.3) | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV99584276; called by muse, varscan2
- TAFA1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.338); catalogued as rs754121777, COSV72037425; called by muse, mutect2, varscan2
- TECTA | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as rs764994708, COSV50705867; called by muse, mutect2
- TG | c.7466G>A p.R2489H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs143135039; called by muse, mutect2
- TIAM1 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99739896; called by muse, mutect2, varscan2
- TMEM178A | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV99931783; called by muse, mutect2
- TMPRSS6 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 90/169 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs772270379, COSV100696250; called by muse, mutect2, varscan2
- TP53BP1 | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs751008850, COSV99781767; called by muse, mutect2, varscan2
- TRPM2 | c.466C>A p.H156N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100309502; called by muse, mutect2, varscan2
- TRPM8 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 28/131 reads (21%) | catalogued as COSV100224758, COSV61223445; called by muse, mutect2, varscan2
- TTLL2 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as rs767071019, COSV99515049; called by muse, mutect2, varscan2
- TUBB4A | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV51156178; called by muse, mutect2
- UTP20 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as rs1371439798, COSV99882780; called by muse, mutect2, varscan2
- VCAN | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427826; called by muse, mutect2, varscan2
- ZNF140 | c.712A>C p.T238P | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100166851, COSV100166893; called by muse, mutect2, varscan2
- DNAH7 | c.8804_8805del p.T2935Ifs*12 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- SH3BP4 | c.1860del p.Q622Kfs*114 | Frame Shift Del (DEL) | VAF 72/201 reads (36%) | called by mutect2, pindel, varscan2
- ABCC1 | c.1290C>T p.D430= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as rs371886235, COSV60683300; called by muse, mutect2, varscan2
- BRF1 | c.1953C>T p.D651= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1387338819, COSV59267473; called by muse, mutect2, varscan2
- CTSV | c.186C>T p.H62= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV99414461; called by muse, mutect2, varscan2
- DAPK1 | c.1542C>A p.P514= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100802948; called by muse, mutect2, varscan2
- GLI3 | c.3585C>T p.N1195= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs765946554, COSV67886265; called by muse, mutect2, varscan2
- GRIN2A | c.2196C>G p.A732= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100411448; called by muse, mutect2, varscan2
- KRTAP20-2 | c.105G>T p.L35= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100424556; called by muse, mutect2, varscan2
- LRRC37A3 | c.1806G>T p.V602= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- MICALL2 | c.2448C>T p.G816= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs568037566, COSV99876381; called by mutect2, varscan2
- MMS22L | c.2262A>T p.P754= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99247927; called by muse, mutect2, varscan2
- NPSR1 | c.90G>A p.V30= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV100707342; called by muse, mutect2, varscan2
- OR2M4 | c.801G>A p.T267= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as rs757716230, COSV60708501; called by muse, mutect2, varscan2
- OR2T1 | c.477C>T p.T159= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs745306052, COSV100822370; called by muse, mutect2, varscan2
- PKD1 | c.3312C>T p.T1104= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs768062013, COSV99237534, COSV99239330; called by muse, mutect2, varscan2
- PRAM1 | c.1797G>A p.K599= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99725943; called by muse, mutect2, varscan2
- SLC46A2 | c.579T>C p.H193= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs1021207677, COSV100953538; called by muse, mutect2, varscan2
- SUCO | c.141C>T p.C47= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs376930360, CM152026; called by muse, mutect2, varscan2
- TAF4 | c.2046G>A p.P682= | Silent (SNP) | VAF 98/227 reads (43%) | catalogued as rs144736719; called by muse, mutect2, varscan2
- TECTA | c.4005G>A p.G1335= | Silent (SNP) | VAF 271/1064 reads (25%) | catalogued as COSV99881993; called by muse, mutect2, varscan2
- TEKT4 | c.807G>T p.L269= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs111598357, COSV54626288, COSV99726838; called by muse, mutect2, varscan2
- TREX2 | c.54T>C p.D18= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs782750935, COSV100444396; called by muse, mutect2, varscan2
- UTP20 | c.4368C>A p.I1456= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV99882782; called by muse, mutect2, varscan2
- ENSA | c.184-680G>A | Intron (SNP) | VAF 12/79 reads (15%) | catalogued as rs138939023; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-192G>C | Intron (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100514646; called by muse, mutect2
